Somatic mutation profile of tumor specimen TCGA-N9-A4Q1-01A (aliquot TCGA-N9-A4Q1-01A-11D-A28R-08) from TCGA case TCGA-N9-A4Q1, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage II; Age at diagnosis: 70.6 years (25,791 days).
Specimen TCGA-N9-A4Q1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed943d80-7d0b-4411-8ee3-fa37d20afcee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N9-A4Q1-10B (Blood Derived Normal), aliquot TCGA-N9-A4Q1-10B-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51f09063-57e5-4ef3-a19c-5c06f2e9104e

The open-access MAF lists 44 somatic variants for this specimen: 41 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 35, Silent 3, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 54/58 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALCAM | c.958dup p.S320Kfs*25 | Frame Shift Ins (INS) | VAF 29/65 reads (45%) | catalogued as rs779048551; called by mutect2, varscan2
- AMY2A | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104434628; called by muse, mutect2
- CAP2 | c.1396T>G p.S466A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV57734575; called by muse, mutect2, varscan2
- CTNNBL1 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs760964033, COSV63743596; called by muse, mutect2, varscan2
- DSCAM | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1432629129, COSV68648785; called by muse, mutect2, varscan2
- FAM50B | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 85/165 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs759641838; called by muse, mutect2, varscan2
- FAP | c.11G>C p.W4S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV99502005; called by muse, mutect2, varscan2
- IGHV3-13 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.47); catalogued as rs1555437090; called by muse, mutect2
- KLF5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614378, COSV66615313; called by muse, mutect2, varscan2
- MCF2L2 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61048643; called by muse, mutect2, varscan2
- NCK1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1228584580, COSV56637879; called by muse, mutect2, varscan2
- NCKAP1 | c.446G>C p.R149P | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62940642; called by muse, mutect2, varscan2
- NEB | c.11716C>T p.R3906W | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368167657; called by muse, mutect2, varscan2
- RALGAPA1 | c.3839C>T p.S1280L | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs995594359; called by muse, mutect2, varscan2
- SALL4 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs1402411509; called by muse, mutect2, varscan2
- SI | c.2985A>G p.I995M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs766550125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZC3H13 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763604474, COSV54449272, COSV99667632; called by muse, mutect2, varscan2
- ZC3H3 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs750725511; called by muse, mutect2, varscan2
- ABCA9 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 317/342 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ADCK2 | c.696del p.G233Afs*18 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
- AMPH | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CP | c.1696C>A p.H566N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPHL1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- HOMEZ | c.197G>C p.S66T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB4 | c.1873C>T p.L625F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- KIF21A | c.1906G>T p.E636* (on ENST00000361418 / NM_001378440.1; = p.E623* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- MMS22L | c.1248G>T p.W416C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCOA6 | c.5458G>A p.V1820M | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- OR2M2 | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR2T4 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PARPBP | c.1738_1740dup | Nonsense Mutation (INS) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- PI4KB | c.1767G>T p.E589D (on ENST00000368873 / NM_001369623.1; = p.E601D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PLEKHG6 | c.1922_1924del p.P641del | In Frame Del (DEL) | VAF 43/92 reads (47%) | called by pindel, varscan2
- RFC4 | c.580T>C p.C194R | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2
- SCLT1 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SDK1 | c.3226C>A p.L1076M | Missense Mutation (SNP) | VAF 96/117 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SOX5 | c.1579_1580insA p.L527Hfs*6 | Frame Shift Ins (INS) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- STXBP5L | c.2555G>T p.C852F | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS11F | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZNF518B | c.1203A>C p.E401D | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- HDX | c.315C>A p.V105= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as rs762463084; called by muse, mutect2, varscan2
- HNRNPL | c.1200C>T p.F400= | Silent (SNP) | VAF 48/58 reads (83%) | catalogued as rs267605470, COSV55493768; called by muse, mutect2, varscan2
- OR5H2 | c.508A>C p.R170= | Silent (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
